TCGA case TCGA-95-7039 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - Emory. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ae702159-5b6a-41dd-868c-7540f9e1131c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 54.7 years (19,981 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 58.1 years (21,239 days); Days to diagnosis: 1,258 days (3.4 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Days to follow up: 34 days; Disease response: Tumor Free.
- Day 1,258 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,258 days (3.4 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 1,272 days (3.5 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 34.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-95-7039-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-95-7039-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-95-7039-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 75; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-95-7039-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-95-7039-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Upper.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 3, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 3, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging; New tumor event diagnosis evidence: Positive Biomarker(s).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,272 days; disease-specific survival: no event (censored), 1,272 days; disease-free interval: event (new tumor event after initially disease-free), 1,258 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,258 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-95-7039-01A-11D-1943-01): tumor purity 0.41, ploidy 5.66, whole-genome doublings 2.
